TCGA case TCGA-ZS-A9CE — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Tayside Tissue Bank. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7bdc5f86-4d7d-4f1f-bc23-ab51fa9fb947

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United Kingdom; Age at index: 79 years; Vital status: Alive.

Diagnoses (3)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 79.5 years (29,051 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G1; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,241 days (3.4 years); Child pugh classification: A; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Micro.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Basaloid squamous cell carcinoma: ICD-O-3 morphology code: 8083/3; Tissue or organ of origin: Lower limb, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 74.3 years (27,125 days); Days to diagnosis: -1,926 days (-5.3 years); AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: MX.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,651 days (-4.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Subsequent primary of the skin of other and unspecified parts of face (histology not recorded by GDC). Age at diagnosis: 82.0 years (29,943 days); Days to diagnosis: 892 days (2.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 892 days (2.4 years); Residual disease: R0.
   Recorded as not given: Ablation or Embolization, NOS, for initial diagnosis; Organ Transplantation to Liver, for initial diagnosis; Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 1,241 days (3.4 years); Disease response: Tumor Free.
- ECOG performance status: 0.
- Follow-up contact recording only the day: day 1,066.

Molecular and laboratory tests
- Platelets 310 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 400].
- Prothrombin Time 36.4 Seconds [Blood test normal range lower: 9; Blood test normal range upper: 12].
- Total Bilirubin 5 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 15].
- Creatinine 78 mg/dL [Blood test normal range lower: 44; Blood test normal range upper: 80].
- Albumin 44 mg/dL [Blood test normal range lower: 36; Blood test normal range upper: 50].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Viral hepatitis serology tests: Hepatitis B Surface Antigen / Hepatitis C Antibody.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZS-A9CE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 10 mg.
  Slide TCGA-ZS-A9CE-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-ZS-A9CE-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
- Sample TCGA-ZS-A9CE-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZS-A9CE-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Single; New tumor event diagnosis indicator: Yes.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis  C Antibody; Viral hepatitis serology: Hepatitis B Surface Antigen.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Right temple; New tumor event liver transplant: No; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event ablation embolization treatment: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Right Temple; New tumor event liver transplant: No; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event ablation embolization treatment: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Leg; Other malignancy histological type: Basaloid Squamous Cell.
- Other malignancy form, Surgery: Other malignancy surgery type: Excision of lesion.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,241 days; disease-specific survival: no event (censored), 1,241 days; disease-free interval: no event (censored), 1,241 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 892 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZS-A9CE-01A-11D-A36W-01): tumor purity 0.77, ploidy 3.74, whole-genome doublings 1.
